Somatic mutation profile of tumor specimen C3N-02259-01 (aliquot CPT0244830006) from CPTAC case C3N-02259, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 84.7 years (30,932 days).
Specimen C3N-02259-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c72f884-e8e9-4cef-a2ea-4451eeea7657.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02259-31 (Blood Derived Normal), aliquot CPT0244850002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f35ef432-3d8f-41b9-993b-68105754f319

The open-access MAF lists 80 somatic variants for this specimen: 55 protein-altering or splice-affecting, 11 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 11, Intron 6, RNA 5, 3'UTR 3, Frame Shift Ins 1, In Frame Del 1, Nonsense Mutation 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AIDA | c.362T>G p.L121W | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1391354230; called by muse, mutect2, varscan2
- ALPK1 | c.2583G>A p.M861I | Missense Mutation (SNP) | VAF 84/318 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs756115435, COSV51584777; called by muse, mutect2, varscan2
- ANKRD62 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 144/501 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.056); catalogued as rs1229945648; called by muse, mutect2, varscan2
- ARHGEF5 | c.4606G>A p.V1536M | Missense Mutation (SNP) | VAF 45/334 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50214156; called by muse, mutect2, varscan2
- CCDC124 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs149338568; called by muse, mutect2, varscan2
- CFAP74 | c.2813C>T p.T938M | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs976978756; called by muse, mutect2, varscan2
- COL6A6 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62038802; called by muse, mutect2, varscan2
- CREBBP | c.1792C>T p.Q598* | Nonsense Mutation (SNP) | VAF 93/381 reads (24%) | catalogued as COSV52144620; called by muse, mutect2, varscan2
- DOK6 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as rs532540997, COSV66926121; called by muse, varscan2
- GPRASP1 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.613); catalogued as rs767215817; called by muse, mutect2, varscan2
- GYG2 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 72/205 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs764375681; called by muse, mutect2, varscan2
- JAK1 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61096343; called by muse, mutect2, varscan2
- KCNA4 | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 77/317 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as rs753892596, COSV60251560; called by muse, mutect2, varscan2
- LRIT3 | c.1855G>A p.D619N | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); catalogued as rs1467611656; called by muse, mutect2, varscan2
- NCKAP1L | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV53214748; called by muse, mutect2
- OR5F1 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1434350535; called by muse, varscan2
- OR6P1 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.564); catalogued as rs188709112; called by muse, mutect2, varscan2
- POSTN | c.1970G>A p.R657H | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs758714986, COSV65712304; called by muse, mutect2, varscan2
- PTPN23 | c.799G>C p.G267R | Missense Mutation (SNP) | VAF 63/248 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146048311; called by muse, mutect2, varscan2
- PTPRC | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 96/345 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781335157, COSV100723180; called by muse, mutect2, varscan2
- PTPRK | c.4145G>A p.R1382Q (on ENST00000368215 / NM_001291984.2; = p.R1383Q on NM_002844.4) | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1239642954, COSV63892039; called by muse, mutect2, varscan2
- RASIP1 | c.1376C>T p.T459M | Missense Mutation (SNP) | VAF 102/381 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs372021729; called by muse, mutect2, varscan2
- SIM1 | c.1880C>A p.T627N | Missense Mutation (SNP) | VAF 105/361 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV53495727; called by muse, mutect2, varscan2
- SLC22A10 | c.182G>C p.G61A | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs1472715381; called by muse, mutect2, varscan2
- SLC25A12 | c.1190T>C p.I397T | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs199764487; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC34A1 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs767807252; called by muse, mutect2, varscan2
- SPDYE4 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs371237439, COSV60905978; called by muse, mutect2, varscan2
- SUPT3H | c.682G>A p.A228T (on ENST00000371460 / NM_181356.3; = p.A217T on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/342 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.338); catalogued as rs748728560, COSV60938616; called by muse, mutect2, varscan2
- TMEM63C | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs763988884, COSV53601774; called by muse, mutect2, varscan2
- WDR45 | c.847G>T p.V283L (on ENST00000376372 / NM_001029896.2; = p.V284L on NM_007075.3) | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1388592135; called by muse, mutect2, varscan2
- ADCY9 | c.3650G>A p.S1217N | Missense Mutation (SNP) | VAF 99/414 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ARHGAP32 | c.2877G>C p.M959I (on ENST00000310343 / NM_001378025.1; = p.M610I on NM_014715.4) | Missense Mutation (SNP) | VAF 85/298 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC159 | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC57 | c.2241G>A p.E747= | Splice Region (SNP) | VAF 67/219 reads (31%) | called by muse, mutect2, varscan2
- CCT7 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- CDC42BPG | c.2129A>T p.E710V | Missense Mutation (SNP) | VAF 81/304 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CNGA2 | c.1200G>C p.K400N | Missense Mutation (SNP) | VAF 109/414 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CXorf66 | c.125A>T p.N42I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- DNAH11 | c.8165T>C p.F2722S | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- FRG2 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- NFAM1 | c.617del p.R206Nfs*90 | Frame Shift Del (DEL) | VAF 39/150 reads (26%) | called by mutect2, pindel, varscan2
- PGM5 | c.339_341del p.A114del | In Frame Del (DEL) | VAF 37/206 reads (18%) | called by mutect2, pindel, varscan2
- PLA2G7 | c.374T>A p.F125Y | Missense Mutation (SNP) | VAF 83/302 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PNPLA4 | c.431T>A p.F144Y | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- POLE2 | c.1514G>T p.S505I | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SERPINA12 | c.863A>C p.Q288P | Missense Mutation (SNP) | VAF 75/308 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- SGCB | c.761G>A p.S254N | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- SIGLEC6 | c.686C>A p.T229N | Missense Mutation (SNP) | VAF 64/263 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- TLL1 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 64/247 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM200A | c.1471T>A p.F491I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TUBGCP2 | c.1327C>A p.L443M | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UGT1A3 | c.512T>A p.F171Y | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- UGT2B28 | c.638dup p.N213Kfs*9 | Frame Shift Ins (INS) | VAF 30/145 reads (21%) | called by mutect2, pindel, varscan2
- ZNF479 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 62/465 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF804A | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- C16orf82 | c.24C>T p.P8= | Silent (SNP) | VAF 120/439 reads (27%) | called by muse, mutect2, varscan2
- CLEC1A | c.831C>T p.G277= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as rs548539727, COSV59533153; called by muse, varscan2
- DCBLD1 | c.204C>T p.C68= | Silent (SNP) | VAF 128/526 reads (24%) | catalogued as rs760656181, COSV99756873; called by muse, mutect2, varscan2
- ITGAM | c.1827C>T p.H609= (on ENST00000648685 / NM_001145808.2; = p.H608= on NM_000632.4) | Silent (SNP) | VAF 43/162 reads (27%) | catalogued as rs766214343; called by muse, mutect2, varscan2
- KCNC3 | c.582C>T p.D194= | Silent (SNP) | VAF 142/492 reads (29%) | called by muse, mutect2, varscan2
- MYOCD | c.492G>A p.P164= | Silent (SNP) | VAF 80/297 reads (27%) | catalogued as rs745617618, COSV58507592; called by muse, mutect2, varscan2
- OMA1 | c.1527G>A p.Q509= | Silent (SNP) | VAF 48/192 reads (25%) | called by muse, mutect2, varscan2
- OR1C1 | c.399C>T p.T133= | Silent (SNP) | VAF 54/164 reads (33%) | catalogued as rs758965164, COSV68715325; called by muse, mutect2, varscan2
- SORCS2 | c.1710C>T p.G570= | Silent (SNP) | VAF 24/135 reads (18%) | catalogued as rs141596296; called by muse, mutect2, varscan2
- TENM3 | c.2655G>A p.S885= | Silent (SNP) | VAF 60/220 reads (27%) | catalogued as rs750637583, COSV69299477; called by muse, mutect2, varscan2
- TTLL10 | c.1881C>T p.P627= | Silent (SNP) | VAF 77/221 reads (35%) | catalogued as rs992783483; called by muse, mutect2, varscan2
- AC107023.1 | n.26-11400A>C | Intron (SNP) | VAF 21/95 reads (22%) | called by muse, mutect2
- ATP6AP2 | c.*44T>C | 3'UTR (SNP) | VAF 45/139 reads (32%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*2152C>T | 3'UTR (SNP) | VAF 38/133 reads (29%) | catalogued as rs926386759; called by muse, mutect2, varscan2
- CSMD3 | c.178+59972G>A | Intron (SNP) | VAF 90/351 reads (26%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.1133G>A | RNA (SNP) | VAF 30/896 reads (3%) | catalogued as rs782597932; called by muse, mutect2
- HTR3A | c.916+45G>A | Intron (SNP) | VAF 44/169 reads (26%) | catalogued as rs149205752; called by muse, mutect2, varscan2
- MC2R | c.*38C>T | 3'UTR (SNP) | VAF 73/236 reads (31%) | called by muse, mutect2, varscan2
- MGAT4EP | n.1632C>T | RNA (SNP) | VAF 34/101 reads (34%) | called by muse, mutect2, varscan2
- PDE10A | c.106+91707T>C | Intron (SNP) | VAF 47/149 reads (32%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.295+1746C>T | Intron (SNP) | VAF 59/447 reads (13%) | called by muse, mutect2, varscan2
- RFPL4AP1 | n.399C>T | RNA (SNP) | VAF 149/537 reads (28%) | called by muse, mutect2, varscan2
- RFPL4AP1 | n.625C>T | RNA (SNP) | VAF 129/454 reads (28%) | called by muse, mutect2, varscan2
- RPS4X | c.361-499A>G | Intron (SNP) | VAF 53/159 reads (33%) | called by muse, mutect2, varscan2
- TPRX2P | n.767G>A | RNA (SNP) | VAF 84/327 reads (26%) | catalogued as rs760107110; called by muse, mutect2, varscan2
